Somatic mutation profile of tumor specimen TCGA-J4-A83K-01A (aliquot TCGA-J4-A83K-01A-11D-A34U-08) from TCGA case TCGA-J4-A83K, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 52.8 years (19,299 days).
Specimen TCGA-J4-A83K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f212f355-32e9-435a-b13b-6b7da98fdd15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-A83K-10A (Blood Derived Normal), aliquot TCGA-J4-A83K-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea1734b9-cdaa-45d8-a4f5-0905bc934776

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 13, Silent 6, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARNT2 | c.838G>C p.V280L | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs1198626475, COSV100309274; called by muse, mutect2, varscan2
- BACH2 | c.1420C>T p.L474F | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as COSV100000333, COSV57593317; called by muse, mutect2, varscan2
- BCHE | c.1694A>T p.D565V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100012839; called by muse, mutect2, varscan2
- CPNE9 | c.579A>C p.K193N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as COSV99808386; called by muse, mutect2, varscan2
- DEFB118 | c.99C>G p.H33Q | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.177); catalogued as COSV99489282; called by muse, mutect2
- GLUD2 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs751112189, COSV60153634; called by muse, mutect2, varscan2
- IRS2 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65480068; called by muse, mutect2, varscan2
- KIAA1217 | c.4622C>T p.T1541M | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs148213717; called by muse, mutect2, varscan2
- MUC16 | c.12883G>A p.E4295K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs866967106, COSV67470836; called by muse, mutect2, varscan2
- PCDHA2 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV65368520; called by muse, mutect2, varscan2
- STAT3 | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99232995; called by muse, mutect2, varscan2
- STX1A | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV99736782; called by muse, mutect2
- THSD1 | c.2281C>T p.R761W | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs749838055, COSV99318990; called by muse, varscan2
- ZSCAN16 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100481513; called by muse, mutect2
- SH3TC2 | c.1573del p.W525Gfs*13 | Frame Shift Del (DEL) | VAF 48/144 reads (33%) | called by mutect2, pindel, varscan2
- C6 | c.1212A>T p.T404= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV99667466; called by muse, mutect2
- CDK5 | c.624C>A p.V208= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99877193; called by muse, mutect2, varscan2
- GAB4 | c.1713C>T p.G571= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs372257366; called by muse, mutect2, varscan2
- LGR5 | c.2307C>A p.A769= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as COSV57009132, COSV99878202; called by muse, mutect2, varscan2
- PNMA8B | c.951G>A p.Q317= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV100885479; called by muse, mutect2, varscan2
- PTPN5 | c.906G>A p.A302= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs781071029, COSV62125748; called by muse, mutect2, varscan2
